Surgical pathology report (de-identified scan), TCGA case TCGA-64-1680, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-64-1680-01A (Primary Tumor).

[page 1 of 4]
Clinical History/Diagnosis: Right Lung Cancer

Source of Specimen(s):

- 1: Cytology -no fee code
- 2: Cytology -no fee code
- 3: Cytology -no fee code
- 4: Cytology -no fee code
- 5: Cytology -no fee code
- 6: portion of 6th rib
- 7: level 9 lymph node
- 8: level 7 lymph nodes
- 9: 10R lymph nodes
- 10: level 11 lymph nodes
- 11: right middle and lower lobes of lung
- 12: 4R lymph nodes

Gross Description:

Received in twelve parts.

Source of Tissue: 1. Cytology Specimen

Source of Tissue: 2. Cytology Specimen

Source of Tissue: 3. Cytology Specimen

Source of Tissue: 4. Cytology Specimen

Source of Tissue: 5. Cytology Specimen

Source of Tissue: 6. Labeled # 6, "portion of 6th rib"

Gross Description: Received fresh in a container labeled "patient name and medical number, portion of 6th rib". It consists of a fragment of rib measuring 2.0 x 1.9 x 1.5 cm. There are no suspicious lesions or masses and the specimen contains attached associated skeletal muscle.

Representative sections are submitted in 6A following decalcification.

Source of Tissue: 7. Labeled # 7, "level 9 lymph node"

[page 2 of 4]
Gross Description: Received fresh in a container labeled " patient name and medical number, level 9 lymph node". It consists of a single grayish black lymph node measuring 0.7 x 0.6 x 0.6 cm. It is unremarkable and entirely submitted in 7A.

Source of Tissue: 8. Labeled # 8, "level 7 lymph nodes"

Gross Description: Received fresh in a container labeled " patient name and medical number, level 7 lymph nodes". It consists of multiple gray-black lymph nodes and attached associated fat measuring from 0.6 up to 1.5 cm. Entirely submitted in 8A and 8B.

Source of Tissue: 9. Labeled # 9, "10R lymph nodes"

Gross Description: Received fresh in a container labeled " patient name and medical number, 10R lymph nodes". It consists of three firm grayish black lymph nodes measuring respectively 0.8, 0.9 and 1.5 cm. The larger node is bisected disclosing a fatty cut surface. The two smaller nodes are submitted in toto in 9A and the larger node is bisected and submitted in 9B. Entirely submitted in 9A and 9B.

Source of Tissue: 10. Labeled # 10, "level 11 lymph nodes"

Gross Description: Received fresh in a container labeled " patient name and medical number, level 11 lymph nodes". It consists of a few grayish black fragments of lymph nodes and tissue measuring from 0.4 up to 1.2 cm. The tissue is unremarkable. Submitted in toto in 10A.

Source of Tissue: 11. Labeled # 11, "right middle and lower lobe of lung"

Frozen Section Diagnosis: 11FS- NEGATIVE MARGINS.

Gross Description: Received fresh from O.R. for frozen section consultation in a container labeled " patient name and medical number, right middle and lower lobe of lung". It consists of a 440-gram right middle and lower lobe of lung measuring respectively 12.0 x 7.0 x 6.0 and 16.0 x 16.0 x 7.0 cm. The bronchial margin was procured for frozen section and the residue is in 11FS. The bronchial tree is opened and is unremarkable. The vascular margins are likewise unremarkable. Sections through the lower lobe disclose a few ill-defined tiny areas of fullness measuring no more than 0.3 cm. Elsewhere the parenchyma is pink and spongy. The

[page 3 of 4]
middle lobe is firm. Sections disclose an 8.0 x 6.0 x 4.0 cm light brown bosselated cut surface comprising 70% of the middle lobe. The middle and lower lobes are well-delineated and the sulcus is intact with no gross evidence of tumor extension however the aforementioned small lesions in the lower lobe are suspicious for tumor. Lesional tissue comes within 0.7 cm of the resection margin. Representative sections are submitted in 11A-G.

Designation of Sections: 11FS- bronchial margin, 11A- vascular margins, 11B- lower lobe hilar node, 11C- middle lobe hilar node, 11D-11E- middle lobe lesional tissue, 11F-11G- lower lobe lung tissue with possible lesions

Source of Tissue: 12. Labeled # 12, "4R lymph nodes"

Gross Description: Received fresh in a container labeled " patient name and medical number, 4R lymph nodes". It consists of fibroadipose tissue measuring in aggregate 5.0 x 3.0 x 2.0 cm. Bisection through the tissue discloses a few fatty yellow to soft gray-black lymph nodes measuring from 1.0 up to 1.5 cm. No suspicious areas are grossly identified. Entirely submitted in 12A-D.

Designation of Sections: 12A-12C- single large fatty lymph node, 12D- single lymph nodes

Final Diagnosis:

1. Cytology Specimen

2. Cytology Specimen

3. Cytology Specimen

4. Cytology Specimen

5. Cytology Specimen

6. Portion of 6th rib:

No tumor seen.

7. Level 9 lymph node:

No tumor seen in one lymph node (0/1).

8. Level 7 lymph node:

Metastatic carcinoma in five of fifteen lymph nodes (5/15).

[page 4 of 4]
9. 10R lymph node:

Metastatic carcinoma in two of three lymph nodes (2/3).

10. Level 11 lymph node:

Metastatic carcinoma in one of eight lymph nodes (1/8).

11. Right middle and lower lobe of lung:

Adenocarcinoma, WHO mixed subtype.

- The 8.0 cm moderately differentiated middle lobe carcinoma features acinar, papillary and lepidic growth patterns while lower lobe subcentimeter satellite lesions are similar.

- The middle lobe carcinoma invades into visceral pleura.

- Lymphovascular invasion is identified.

- Surgical resection margins are free of carcinoma.

No tumor seen in ten lymph nodes (0/10).

12. 4R lymph nodes:

Metastatic carcinoma in one of nine lymph nodes (1/9).

pTNM: T2 N2 M1

Source: NCI Genomic Data Commons file bbebe824-0385-432c-8a5d-b6a5fbb41746 (TCGA-64-1680.8DAA91A5-773C-4C8B-AB17-B270AA75EC18.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).